Somatic mutation profile of tumor specimen 0DRSSG from CCDI case PBCGPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (809 days).
Specimen 0DRSSG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 319365ee-1b31-44b4-b094-7609db735013.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRSSB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55944d67-64fc-4fe4-afd8-ce36f7832270

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1889A>G p.Y630C | Missense Mutation (SNP) | VAF 100/1089 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777621655; called by muse, mutect2
- NBEAL2 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 272/579 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1191007923; called by muse, mutect2, varscan2
- TREH | c.959G>T p.W320L | Missense Mutation (SNP) | VAF 237/623 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV50620242; called by muse, mutect2, varscan2
- KMT2C | c.9476T>G p.I3159S | Missense Mutation (SNP) | VAF 40/710 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2
